Somatic mutation profile of tumor specimen MP2PRT-PARUWV-TMP1-A (aliquot MP2PRT-PARUWV-TMP1-A-1-0-D-A81X-36) from MP2PRT case MP2PRT-PARUWV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,112 days).
Specimen MP2PRT-PARUWV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 393ee142-11e9-4f34-93ff-c94164c7553b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARUWV-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARUWV-NB1-A-1-0-D-A81X-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d37e5d8-8ebb-41bb-abf5-b5dfc22ee26e

The open-access MAF lists 23 somatic variants for this specimen: 17 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 16, Silent 6, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>C p.Q61P | Missense Mutation (SNP) | VAF 32/640 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ATP1A1 | c.1990G>A p.V664I | Missense Mutation (SNP) | VAF 32/382 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as rs200285355, COSV99814026; called by muse, mutect2
- BCORL1 | c.4606C>T p.R1536C | Missense Mutation (SNP) | VAF 36/460 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs868071876, COSV54393391, COSV54407721; called by muse, mutect2
- C17orf64 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 53/296 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.022); catalogued as rs1260173974; called by muse, mutect2, varscan2
- CTSC | c.1213C>G p.H405D | Missense Mutation (SNP) | VAF 48/580 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM040990; called by muse, mutect2
- DISP2 | c.3152G>A p.R1051H | Missense Mutation (SNP) | VAF 34/605 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1268388389, COSV99140760; called by muse, mutect2
- LAMA5 | c.469G>A p.V157I | Missense Mutation (SNP) | VAF 41/432 reads (9%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.817); catalogued as rs777376207; called by muse, mutect2
- MAGEC1 | c.2468C>T p.S823L | Missense Mutation (SNP) | VAF 69/513 reads (13%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs866089909, COSV53579038; called by muse, mutect2, varscan2
- NPAS3 | c.331G>A p.D111N (on ENST00000356141 / NM_001164749.2; = p.D81N on NM_022123.3) | Missense Mutation (SNP) | VAF 61/391 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.767); catalogued as rs201385420, COSV58075899, COSV58105393; called by muse, mutect2, varscan2
- PEG3 | c.3147C>G p.N1049K | Missense Mutation (SNP) | VAF 42/376 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1168898381; called by muse, mutect2, varscan2
- PTGS2 | c.1363C>T p.R455C | Missense Mutation (SNP) | VAF 56/384 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs780502264; called by muse, mutect2, varscan2
- TTN | c.58141C>T p.R19381C (on ENST00000591111; = p.R11957C on NM_003319.4) | Missense Mutation (SNP) | VAF 41/384 reads (11%) | PolyPhen probably damaging (0.998); catalogued as rs779112015, COSV59879754; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1E | c.3893T>C p.L1298P | Missense Mutation (SNP) | VAF 57/460 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GTF3C4 | c.2318G>T p.C773F | Missense Mutation (SNP) | VAF 12/311 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- IGHV4-61 | c.353_354insCCGGG p.R118Sfs*? | Frame Shift Ins (INS) | VAF 15/144 reads (10%) | called by mutect2, pindel, varscan2
- OR52N1 | c.368A>T p.D123V | Missense Mutation (SNP) | VAF 38/538 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF474 | c.239G>T p.S80I | Missense Mutation (SNP) | VAF 46/435 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- HUNK | c.1453C>A p.R485= | Silent (SNP) | VAF 40/516 reads (8%) | called by muse, mutect2
- IGHA1 | c.627C>T p.P209= | Silent (SNP) | VAF 70/317 reads (22%) | catalogued as rs372595680; called by muse, mutect2, varscan2
- IGHV4-61 | c.356A>G p.*119= | Silent (SNP) | VAF 12/88 reads (14%) | catalogued as rs781964434; called by mutect2, varscan2
- MARCHF7 | c.1068T>G p.G356= | Silent (SNP) | VAF 43/348 reads (12%) | called by muse, mutect2, varscan2
- PCSK9 | c.420C>T p.V140= | Silent (SNP) | VAF 49/404 reads (12%) | catalogued as rs749630126; ClinVar: likely benign; called by muse, mutect2, varscan2
- TTC36 | c.454C>T p.L152= | Silent (SNP) | VAF 66/983 reads (7%) | called by muse, mutect2
